Gene-level copy-number profile of tumor specimen TCGA-61-1733-01A from TCGA case TCGA-61-1733, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.7 years (26,180 days).
Specimen TCGA-61-1733-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.825d3945-c096-414d-9671-1525b08e6107.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1733-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a651abf5-70c2-4702-a21d-c416d3d696eb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,247; copy number 2: 27,120; copy number 3: 14,585; copy number 4: 9,942; copy number 5: 880; copy number 6: 1,878; copy number 7: 119; copy number 9: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1733-01A-01D-0577-01): tumor purity 0.84, ploidy 2.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,926 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,769,339–164,980,137, 14 genes, copy number 5: AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P.
- chr2:49,878,623–52,702,615, 24 genes, copy number 5: RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431.
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 6 (broad region; genes not listed).
- chr12:66,767–6,914,241, 198 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:27,638,483–34,127,423, 139 genes, copy number 6–9 (broad region; genes not listed).
- chr19:35,399,511–36,605,276, 85 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr19:38,587,641–38,908,893, 20 genes, copy number 6: MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB.
- chr20:38,210,503–64,313,132, 644 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,828. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
